CCDI case PBBYDY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/7362f3d2-f4df-441e-a3d2-6b0bb308d039

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.5 years (535 days).

Biospecimens (3 samples)
- Sample 0DNDZH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNE0A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DNE0P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
